Gene-level copy-number profile of tumor specimen TCGA-LC-A66R-01A from TCGA case TCGA-LC-A66R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 78.8 years (28,793 days).
Specimen TCGA-LC-A66R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a93af166-88fe-4df1-810a-bd87fd7bdab4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LC-A66R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00d9fe8d-7cc2-4d69-b792-9317262ade3f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 8; copy number 2: 11,583; copy number 3: 18,351; copy number 4: 18,531; copy number 5: 6,776; copy number 6: 2,103; copy number 7: 1,506; copy number 8: 221; copy number 9: 210; copy number 10: 210; copy number 11: 203; copy number 12: 30; copy number 13: 4; copy number 14: 13; copy number 19: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LC-A66R-01A-41D-A30D-01): tumor purity 0.37, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:26,514,031–26,658,178, 1 gene (within-gene range 0–2): DPYSL2.
- chr8:26,748,150–27,311,272, 11 genes: ADRA1A, AC091675.1, COX6B1P4, AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 721 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:9,292,588–10,127,190, 40 genes, copy number 9 (within-gene range 5–9): AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3, SETD5, LHFPL4, DUSP5P2, MTMR14, AC022382.2, CPNE9, BRPF1, OGG1, CAMK1, TADA3, ARPC4, ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3, CIDEC, JAGN1, IL17RE, IL17RC, RNU6-882P, AC018809.3, CRELD1, AC018809.1, PRRT3, PRRT3-AS1, AC018809.2, EMC3, EMC3-AS1, CYCSP10, AC022007.1, CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1.
- chr3:10,759,350–14,352,568, 70 genes, copy number 10 (broad region; genes not listed).
- chr3:89,107,621–90,261,708, 8 genes, copy number 11 (within-gene range 4–11): EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr6:6,588,108–7,251,980, 15 genes, copy number 11 (within-gene range 5–11): LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1.
- chr6:11,503,509–14,404,289, 45 genes, copy number 9–11: RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2, HIVEP1, EDN1, SUMO2P12, RN7SKP293, RPL15P3, LINC02530, PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1.
- chr6:20,042,455–22,654,455, 28 genes, copy number 13–19 (within-gene range 4–19): AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1.
- chr6:39,048,781–42,142,620, 75 genes, copy number 9–12 (within-gene range 4–12) (broad region; genes not listed).
- chr6:43,076,307–44,380,179, 60 genes, copy number 9 (within-gene range 4–9): PTK7, SRF, CUL9, AL133375.1, DNPH1, TTBK1, SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1, AL359813.1, AL359813.2, ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1.
- chr6:47,878,028–50,415,875, 32 genes, copy number 12–19: PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1.
- chr6:51,599,723–52,577,060, 13 genes, copy number 14 (within-gene range 7–14): AL355997.1, PKHD1, RN7SL580P, MIR206, LINCMD1, MIR133B, IL17A, IL17F, SLC25A20P1, MCM3, PAQR8, EFHC1, TRAM2.
- chr8:101,287,445–102,412,759, 23 genes, copy number 11 (within-gene range 7–11): AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2, MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1.
- chr10:4,871,901–14,774,897, 181 genes, copy number 9–10 (broad region; genes not listed).
- chr13:107,788,342–114,337,626, 131 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
